Gene-level copy-number profile of tumor specimen TCGA-L5-A4OH-01A from TCGA case TCGA-L5-A4OH, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 71.7 years (26,180 days).
Specimen TCGA-L5-A4OH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.2426187b-3ce5-445d-8af5-2540d7215fab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OH-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/12d8cb11-99b0-41f9-b27a-8440d2cf2616

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 587; copy number 2: 21,625; copy number 3: 18,606; copy number 4: 8,762; copy number 5: 5,516; copy number 6: 3,651; copy number 7: 55; copy number 8: 86; copy number 9: 5; copy number 10: 152; copy number 11: 173; copy number 12: 362; copy number 13: 65; copy number 14: 46; copy number 16: 94; copy number 21: 2; copy number 30: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OH-01A-11D-A25X-01): tumor purity 0.63, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr16:78,525,189–78,535,648, 2 genes: AC046158.4, AC046158.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,217 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr4:89,410,960–89,999,409, 9 genes, copy number 5: AC093866.1, AC097478.4, SNCA, AC097478.1, AC097478.3, AC097478.2, SNCA-AS1, MMRN1, AC105445.1.
- chr4:148,078,762–148,444,698, 1 gene, copy number 5 (within-gene range 3–5): NR3C2.
- chr4:148,445,703–190,092,279, 586 genes, copy number 5 (broad region; genes not listed).
- chr5:176,880,869–181,342,213, 180 genes, copy number 6–12 (within-gene range 2–12) (broad region; genes not listed).
- chr6:167,607–1,613,897, 32 genes, copy number 5: AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1.
- chr6:66,710,242–66,728,904, 2 genes, copy number 5: AL450336.1, RNU7-66P.
- chr7:70,972–159,233,377, 3,014 genes, copy number 6–7 (broad region; genes not listed).
- chr8:86,707,547–87,615,219, 4 genes, copy number 5 (within-gene range 2–14): AC090572.3, AC090572.2, AC090572.1, CNBD1.
- chr8:95,947,781–104,589,024, 189 genes, copy number 5–10 (broad region; genes not listed).
- chr8:105,546,089–129,683,770, 274 genes, copy number 5–12 (within-gene range 2–12) (broad region; genes not listed).
- chr8:133,036,728–133,102,912, 1 gene, copy number 30 (within-gene range 4–30): SLA.
- chr8:133,191,039–134,390,487, 21 genes, copy number 11–30: CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1.
- chr8:135,457,456–138,083,657, 12 genes, copy number 7–14 (within-gene range 2–14): KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2.
- chr8:138,588,235–139,463,016, 5 genes, copy number 5–13 (within-gene range 2–13): COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1.
- chr9:32,293,558–35,690,056, 155 genes, copy number 5–12 (broad region; genes not listed).
- chr9:38,360,427–43,045,120, 139 genes, copy number 5–11 (broad region; genes not listed).
- chr10:116,427,847–118,267,710, 35 genes, copy number 5–6 (within-gene range 3–6): PNLIPRP3, HMGB3P8, RNU6-1090P, PNLIP, PNLIPP1, PNLIPRP1, PNLIPRP2, C10orf82, AC016825.1, HSPA12A, RPL5P27, ENO4, SHTN1, AC023283.1, AC012308.1, VAX1, MIR3663HG, MIR3663, RPL12P26, KCNK18, AL731557.1, SLC18A2, AL391988.1, PDZD8, AC005871.2, EMX2OS, EMX2, AC005871.1, AL356419.1, LINC02674, AL513324.1, RAB11FIP2, AC022395.1, CASC2, AL354863.1.
- chr11:5,571,247–6,799,689, 74 genes, copy number 6 (broad region; genes not listed).
- chr11:6,843,664–6,846,705, 2 genes, copy number 6: AC087280.1, OR10A5.
- chr11:65,066,300–135,075,908, 1,643 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:27,756,766–29,551,903, 112 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr17:47,253,827–48,997,492, 92 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:49,004,731–49,018,061, 2 genes, copy number 5: AC091133.4, Metazoa_SRP.
- chr17:66,638,271–67,697,261, 25 genes, copy number 6–11 (within-gene range 2–11): RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1.
- chr17:69,355,133–70,368,916, 15 genes, copy number 7: AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1.
- chr20:87,250–10,368,776, 232 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:30,278,906–61,083,750, 754 genes, copy number 6–16 (broad region; genes not listed).
- chr20:61,267,525–61,437,630, 3 genes, copy number 9: AL365229.1, BX640515.1, AL160412.1.

Autosomal genes at a single copy (total copy number 1): 587. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
